CCDI case PBCBRX — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS.
https://portal.gdc.cancer.gov/cases/6bc0fe2a-54c5-4cbc-bd17-6564cd86ea07

Demographics
Sex at birth: male; Race: black or african american.

Diagnoses (1)
1. Myxofibrosarcoma: ICD-O-3 morphology code: 8811/3; Tissue or organ of origin: Scrotum, NOS; Age at diagnosis: 15.3 years (5,578 days).

Biospecimens (3 samples)
- Sample 0DOA26: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DOA2X: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DOA3P: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
